Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040036-03A.1 (aliquot TARGET-15-SJMPAL040036-03A.1-01D) from TARGET case TARGET-15-SJMPAL040036, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,983 days).
Specimen TARGET-15-SJMPAL040036-03A.1: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fc604ea-dbc8-4ab5-9ba1-bb285ab9a65d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040036-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040036-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2934d997-460b-46e4-8938-12885026e2c9

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 5, Frame Shift Ins 2, RNA 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15061C>T p.R5021* | Nonsense Mutation (SNP) | VAF 53/116 reads (46%) | catalogued as rs587783695, CM122109, COSV56415919; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.4142C>A p.S1381* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV60686353; called by muse, mutect2
- FCN2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs767686429; called by muse, mutect2, varscan2
- OLFM2 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233551999; called by muse, mutect2
- PLAAT1 | c.389G>A p.R130H (on ENST00000650797; = p.R25H on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs150318874; called by muse, mutect2, varscan2
- TNIP3 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs778852023, COSV50249949; called by muse, mutect2, varscan2
- WT1 | c.1072delinsGG p.R358Gfs*15 | Frame Shift Ins (INS) | VAF 59/191 reads (31%) | catalogued as COSV60069873, COSV60081928; called by pindel, varscan2*
- EPX | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- GJC2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- LONRF3 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP8 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- NTN1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RUNX1 | c.540_541insAGGG p.Q181Rfs*6 (on ENST00000344691 / NM_001001890.3; = p.Q208Rfs*6 on NM_001754.5) | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- TLN2 | c.3584C>A p.S1195* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- VSTM2A | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF415 | c.339C>T p.A113= | Silent (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- AGAP7P | n.2051G>A | RNA (SNP) | VAF 6/148 reads (4%) | catalogued as rs560889711; called by muse, mutect2
